Somatic mutation profile of tumor specimen C3N-04127-01 (aliquot CPT0238110010) from CPTAC case C3N-04127, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 63.4 years (23,148 days).
Specimen C3N-04127-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 065bde58-b8c7-4589-895c-0233615d4f09.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-04127-31 (Blood Derived Normal), aliquot CPT0238170002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e5fc2ce3-0995-4fc3-9b06-33250960d7e7

The open-access MAF lists 78 somatic variants for this specimen: 56 protein-altering or splice-affecting, 17 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 48, Silent 17, Intron 4, Nonsense Mutation 2, Splice Site 2, Splice Region 2, Frame Shift Ins 1, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LDLR | c.971del p.G324Afs*46 | Frame Shift Del (DEL) | VAF 56/546 reads (10%) | catalogued as rs879254745, CM983995, COSV52943111; ClinVar: pathogenic; called by mutect2, varscan2
- TP53 | c.730G>T p.G244C | Missense Mutation (SNP) | VAF 28/329 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519989, CM144215, COSV52668392, COSV52676997, COSV52808251; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2
- ADAM22 | c.176C>A p.S59* | Nonsense Mutation (SNP) | VAF 14/178 reads (8%) | catalogued as COSV55973954; called by muse, mutect2
- ADAM32 | c.1457A>G p.N486S | Missense Mutation (SNP) | VAF 20/169 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.052); catalogued as COSV65955182; called by muse, mutect2, varscan2
- AGRN | c.6070C>T p.R2024W | Missense Mutation (SNP) | VAF 15/435 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.42); catalogued as rs1183244815; called by muse, mutect2
- ALPK2 | c.4042G>T p.E1348* | Nonsense Mutation (SNP) | VAF 8/154 reads (5%) | catalogued as rs934508145; called by muse, mutect2
- ARRB2 | c.865G>A p.A289T | Missense Mutation (SNP) | VAF 16/212 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs764855635; called by muse, mutect2
- COL1A2 | c.2711G>A p.G904E | Missense Mutation (SNP) | VAF 30/318 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99033062; called by muse, mutect2
- MYH11 | c.3854T>A p.L1285Q | Missense Mutation (SNP) | VAF 40/445 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as COSV100260689; called by muse, mutect2
- OR4K2 | c.404T>C p.V135A | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.044); catalogued as COSV100064810; called by muse, mutect2
- PROS1 | c.557G>T p.C186F | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as CM961174, COSV62398792; called by muse, mutect2, varscan2
- PROX1 | c.1933G>A p.D645N | Missense Mutation (SNP) | VAF 11/141 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.529); catalogued as rs773788297, COSV54777143; called by muse, mutect2
- SNTG1 | c.757G>T p.V253F | Missense Mutation (SNP) | VAF 37/243 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV52435349; called by muse, mutect2, varscan2
- TP53 | c.729G>T p.M243I | Missense Mutation (SNP) | VAF 28/332 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52668406, COSV52782728, COSV52840414; called by muse, mutect2
- TPP1 | c.1637C>A p.T546K | Missense Mutation (SNP) | VAF 18/394 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV54991453; called by muse, mutect2
- ZNF469 | c.4135G>A p.A1379T (on ENST00000437464; = p.A1407T on NM_001367624.2) | Missense Mutation (SNP) | VAF 30/353 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs888435601; called by muse, mutect2
- ABCA12 | c.4924A>G p.M1642V (on ENST00000272895 / NM_173076.3; = p.M1324V on NM_015657.3) | Missense Mutation (SNP) | VAF 8/176 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.014); called by muse, mutect2
- ADCK5 | c.1175+2T>C p.X392_splice | Splice Site (SNP) | VAF 16/250 reads (6%) | called by muse, mutect2
- ANKRD50 | c.1547G>T p.C516F | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.483); called by muse, mutect2
- AOC3 | c.1156G>T p.D386Y | Missense Mutation (SNP) | VAF 32/417 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ARFGEF1 | c.3092C>T p.T1031I | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.703); called by muse, mutect2
- BRWD3 | c.1878T>C p.G626= | Splice Region (SNP) | VAF 12/65 reads (18%) | called by muse, mutect2, varscan2
- BTBD7 | c.2303dup p.A769Sfs*6 | Frame Shift Ins (INS) | VAF 10/94 reads (11%) | called by mutect2, varscan2
- CACNA1E | c.3052C>G p.H1018D | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2
- CCT5 | c.637G>A p.G213S | Missense Mutation (SNP) | VAF 38/399 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.137); called by muse, mutect2
- CREBBP | c.1223A>G p.H408R | Missense Mutation (SNP) | VAF 38/323 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CTNNA1 | c.2165T>C p.I722T | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); called by muse, mutect2
- CYP11B2 | c.655G>A p.A219T | Missense Mutation (SNP) | VAF 41/807 reads (5%) | SIFT tolerated (0.39); PolyPhen benign (0.281); called by muse, mutect2
- DNER | c.881T>C p.V294A | Missense Mutation (SNP) | VAF 8/175 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.007); called by muse, mutect2
- DPP3 | c.1116C>G p.D372E | Missense Mutation (SNP) | VAF 6/147 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- DSCAM | c.5635C>A p.Q1879K | Missense Mutation (SNP) | VAF 13/141 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.637); called by muse, mutect2
- EDNRB | c.864C>A p.D288E (on ENST00000377211 / NM_001201397.1; = p.D198E on NM_000115.5) | Missense Mutation (SNP) | VAF 23/186 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- EFTUD2 | c.94G>A p.D32N | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- GTDC1 | c.802G>C p.V268L | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated, low confidence (0.94); PolyPhen benign (0); called by muse, mutect2
- HBD | c.187G>A p.A63T | Missense Mutation (SNP) | VAF 32/489 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.359); called by muse, mutect2
- HDC | c.720+3A>T | Splice Region (SNP) | VAF 20/230 reads (9%) | called by muse, mutect2
- HNRNPU | c.467A>G p.N156S | Missense Mutation (SNP) | VAF 56/676 reads (8%) | SIFT tolerated (0.91); PolyPhen benign (0.009); called by muse, mutect2
- IGF2R | c.5985A>T p.K1995N | Missense Mutation (SNP) | VAF 12/207 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); called by muse, mutect2
- KNTC1 | c.4609A>G p.I1537V | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- LGSN | c.833C>T p.S278L | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- NPR2 | c.1712T>C p.M571T | Missense Mutation (SNP) | VAF 26/253 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- OR11H2 | c.329C>G p.S110C (on ENST00000556246; = p.S121C on NM_001197287.1) | Missense Mutation (SNP) | VAF 17/505 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); called by muse, mutect2
- OR2B11 | c.79C>G p.L27V | Missense Mutation (SNP) | VAF 33/236 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.351); called by muse, mutect2, varscan2
- OR2D3 | c.307G>C p.V103L | Missense Mutation (SNP) | VAF 14/184 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2
- PCDH17 | c.1214G>C p.G405A | Missense Mutation (SNP) | VAF 30/278 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- PIKFYVE | c.3644A>T p.H1215L | Missense Mutation (SNP) | VAF 22/308 reads (7%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.986); called by muse, mutect2
- PPP4R4 | c.1243A>C p.T415P | Missense Mutation (SNP) | VAF 11/113 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- PZP | c.2468A>G p.Y823C | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RTN1 | c.1015+1G>T p.X339_splice | Splice Site (SNP) | VAF 4/46 reads (9%) | called by muse, mutect2
- SHANK1 | c.2056C>T p.P686S | Missense Mutation (SNP) | VAF 7/105 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); called by muse, mutect2
- SPAG16 | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- SUN1 | c.2363A>G p.D788G (on ENST00000405266 / NM_001367651.1; = p.D668G on NM_025154.6 and 13 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.822); called by muse, mutect2, varscan2
- TMEM67 | c.483G>A p.M161I | Missense Mutation (SNP) | VAF 11/167 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2
- TTN | c.20050A>G p.K6684E (on ENST00000591111; = p.K5757E on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/115 reads (5%) | PolyPhen benign (0.163); called by muse, mutect2
- WSCD1 | c.1177T>G p.F393V | Missense Mutation (SNP) | VAF 18/154 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ZNF292 | c.1568A>T p.Q523L | Missense Mutation (SNP) | VAF 20/192 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- ADAMTS15 | c.255C>A p.G85= | Silent (SNP) | VAF 15/162 reads (9%) | called by muse, mutect2
- ADGRG4 | c.4617T>C p.S1539= | Silent (SNP) | VAF 9/31 reads (29%) | called by muse, mutect2, varscan2
- AOC3 | c.1155G>T p.V385= | Silent (SNP) | VAF 32/420 reads (8%) | called by muse, mutect2
- EYS | c.501G>T p.V167= | Silent (SNP) | VAF 8/77 reads (10%) | catalogued as COSV60982923; called by muse, mutect2, varscan2
- FTL | c.84C>A p.S28= | Silent (SNP) | VAF 40/582 reads (7%) | called by muse, mutect2
- HAPLN1 | c.330T>A p.G110= | Silent (SNP) | VAF 11/91 reads (12%) | called by muse, mutect2, varscan2
- INSIG2 | c.210A>T p.A70= | Silent (SNP) | VAF 12/80 reads (15%) | called by muse, mutect2, varscan2
- ITGA4 | c.771T>C p.A257= | Silent (SNP) | VAF 5/80 reads (6%) | called by muse, mutect2
- OBSCN | c.5802C>T p.D1934= | Silent (SNP) | VAF 34/439 reads (8%) | catalogued as rs756389960, COSV52780992; called by muse, mutect2
- OR2H1 | c.879G>A p.K293= | Silent (SNP) | VAF 16/166 reads (10%) | catalogued as COSV101009905; called by muse, mutect2
- PAX5 | c.525C>A p.A175= | Silent (SNP) | VAF 14/256 reads (5%) | called by muse, mutect2
- POTEM | c.114C>T p.S38= | Silent (SNP) | VAF 52/760 reads (7%) | catalogued as rs371911516; called by muse, varscan2
- PPFIA4 | c.30G>A p.E10= | Silent (SNP) | VAF 26/153 reads (17%) | called by muse, mutect2, varscan2
- RALGAPA2 | c.4710A>G p.Q1570= | Silent (SNP) | VAF 15/172 reads (9%) | called by muse, mutect2
- TRIM47 | c.1071C>T p.L357= | Silent (SNP) | VAF 26/253 reads (10%) | catalogued as rs776626071; called by muse, mutect2, varscan2
- TSPY1 | c.639T>C p.N213= | Silent (SNP) | VAF 26/974 reads (3%) | called by muse, mutect2
- ZC3H3 | c.2112C>G p.V704= | Silent (SNP) | VAF 19/200 reads (10%) | called by muse, mutect2
- ABCC5 | c.3694+217T>C | Intron (SNP) | VAF 24/350 reads (7%) | called by muse, mutect2
- AXIN1 | c.2463-14C>T | Intron (SNP) | VAF 12/193 reads (6%) | catalogued as rs776899968; called by muse, mutect2
- BLOC1S5 | c.326-938C>A | Intron (SNP) | VAF 9/88 reads (10%) | called by muse, mutect2
- MAP3K3 | c.126+1944G>A | Intron (SNP) | VAF 12/249 reads (5%) | catalogued as rs1325937725; called by muse, mutect2
- XIST | n.8298T>A | RNA (SNP) | VAF 12/80 reads (15%) | called by muse, mutect2, varscan2
